Somatic mutation profile of tumor specimen PCProject_0181_T2_WES (aliquot PCProject_0181_T2_WES_1) from CMI case PCProject_0181, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.2 years (23,805 days).
Specimen PCProject_0181_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27366601-bda7-4807-8395-351034b00bfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0181_SALIVA (Saliva), aliquot PCProject_0181_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba568416-a870-4129-a19b-26218054af3e

The open-access MAF lists 80 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Intron 15, Silent 14, 3'UTR 4, Frame Shift Del 3, Nonsense Mutation 3, 5'UTR 3, 3'Flank 2, RNA 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.655C>A p.R219S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51646097, COSV51647749; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 236/368 reads (64%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACUL1 | c.577_580del p.R193Sfs*19 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs995122409; called by mutect2, pindel
- FCRLA | c.953C>T p.P318L (on ENST00000367959; = p.P295L on NM_032738.4) | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs762589067, COSV52685803, COSV99376552; called by muse, mutect2, varscan2
- GFPT2 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.228); catalogued as rs977514512, COSV53807094; called by muse, mutect2, varscan2
- GTPBP3 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 146/368 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1438104857; called by muse, mutect2, varscan2
- HPSE2 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65185258; called by muse, mutect2
- KCNQ1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs199472688, CM057163, COSV50107676; ClinVar: not provided; called by muse, mutect2, varscan2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- KRTAP11-1 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV60095103; called by muse, mutect2, varscan2
- LMNA | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs267607570, CM082919, COSV100738529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTO1 | c.1156A>C p.M386L | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs997481152, COSV64773224; called by muse, varscan2
- PLCL1 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771861039; called by mutect2, varscan2
- PRKACG | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99598314; called by muse, mutect2, varscan2
- RTL1 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV101128484; called by muse, mutect2
- SLC29A2 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 79/525 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1433003361; called by muse, mutect2, varscan2
- SNAI3 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60002523; called by muse, mutect2, varscan2
- CACNA1D | c.3899del p.P1300Qfs*24 (on ENST00000350061 / NM_001128840.3; = p.P1320Qfs*24 on NM_000720.4) | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- CCDC168 | c.6521G>A p.R2174K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CD1E | c.922_924delinsTT p.I309Sfs*2 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by pindel, varscan2*
- DACT2 | c.1327A>G p.S443G | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.389); called by muse, mutect2
- DIO3 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 75/539 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH1 | c.1152C>G p.N384K | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBF4 | c.1060C>T p.Q354* (on ENST00000609451; = p.Q350* on NM_001110514.1) | Nonsense Mutation (SNP) | VAF 33/312 reads (11%) | called by muse, mutect2, varscan2
- FZD10 | c.1212C>A p.C404* | Nonsense Mutation (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- KDM6B | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 92/922 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2
- KMT2C | c.14320dup p.Y4774Lfs*19 | Frame Shift Ins (INS) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- NFKB1 | c.1760A>G p.H587R (on ENST00000394820 / NM_001382627.1; = p.H588R on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP8 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PEAR1 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- POU6F2 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGSL1 | c.97-7T>A | Splice Region (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- SEMA5A | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- SLC22A14 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLX1B | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TACSTD2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- WDFY4 | c.5326G>C p.A1776P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by mutect2, varscan2
- ZMYND15 | c.1450C>A p.P484T | Missense Mutation (SNP) | VAF 148/279 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF143 | c.1889A>C p.Q630P | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ZNF682 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.53); called by mutect2, varscan2
- ACAT1 | c.27C>G p.R9= | Silent (SNP) | VAF 428/1418 reads (30%) | called by muse, mutect2, varscan2
- ARFIP2 | c.567G>A p.Q189= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV99601568; called by muse, mutect2, varscan2
- COQ7 | c.591C>G p.A197= | Silent (SNP) | VAF 110/336 reads (33%) | catalogued as COSV100430498, COSV58982124; called by muse, mutect2, varscan2
- DOCK8 | c.5769C>T p.H1923= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs145689180; called by muse, mutect2, varscan2
- ITGA9 | c.2121C>T p.S707= | Silent (SNP) | VAF 44/292 reads (15%) | catalogued as rs537086875; called by muse, mutect2, varscan2
- KIAA1522 | c.36C>G p.A12= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1483573369; called by muse, mutect2, varscan2
- KIRREL1 | c.1527C>T p.L509= | Silent (SNP) | VAF 39/191 reads (20%) | catalogued as rs1558019901; called by muse, mutect2, varscan2
- OR5L2 | c.114G>A p.T38= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1342063295; called by muse, mutect2, varscan2
- PLEKHG1 | c.963C>T p.Y321= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs781601317, COSV62048914; called by mutect2, varscan2
- PML | c.1017C>T p.Y339= | Silent (SNP) | VAF 47/128 reads (37%) | catalogued as rs749092993, COSV99167808; called by muse, mutect2, varscan2
- RNASE11 | c.226C>T p.L76= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs370914507; called by mutect2, varscan2
- TMC5 | c.1702C>T p.L568= (on ENST00000396229 / NM_001105248.1; = p.L322= on NM_024780.5) | Silent (SNP) | VAF 59/211 reads (28%) | called by muse, mutect2, varscan2
- TNR | c.735C>T p.C245= | Silent (SNP) | VAF 71/129 reads (55%) | called by muse, mutect2, varscan2
- TTN | c.62466A>G p.V20822= (on ENST00000591111; = p.V13398= on NM_003319.4) | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs1013140499; called by muse, mutect2, varscan2
- ACTN4 | c.-38G>A | 5'UTR (SNP) | VAF 55/320 reads (17%) | called by muse, mutect2, varscan2
- AP002495.1 | c.436+317T>C | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as rs1201342231; called by muse, mutect2
- AP4S1 | c.306+2945A>G | Intron (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- ART3 | c.847+75A>G | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs1442799326; called by muse, mutect2
- ATXN3 | c.-9C>A | 5'UTR (SNP) | VAF 130/252 reads (52%) | catalogued as rs1168471188; called by muse, mutect2, varscan2
- C15orf40 | c.366+56A>G | Intron (SNP) | VAF 14/188 reads (7%) | catalogued as rs781174824, COSV58450738; called by muse, mutect2
- CA13 | c.38-896C>A | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- CENPL | c.420+719A>G | Intron (SNP) | VAF 7/140 reads (5%) | catalogued as COSV61891563; called by muse, mutect2
- CERS5 | c.198-10180A>G | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, varscan2
- DGAT1 | c.676+46A>T | Intron (SNP) | VAF 65/128 reads (51%) | called by muse, mutect2, varscan2
- DUX4L8 | n.554A>C | RNA (SNP) | VAF 14/67 reads (21%) | catalogued as rs1249213756; called by mutect2, varscan2
- GLYCTK | c.*58C>T | 3'UTR (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2
- HECW1 | c.4019+13976A>G | Intron (SNP) | VAF 7/72 reads (10%) | catalogued as rs1027075694; called by muse, mutect2
- LINC02035 | n.86T>C | RNA (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- MARK2 | c.1961+43C>G | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs773479141, COSV59285047; called by muse, varscan2
- MKRN2OS | chr3:12539174 T>C | 3'Flank (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- PPIL2 | c.715-764A>G | Intron (SNP) | VAF 8/94 reads (9%) | catalogued as rs928163119; called by muse, mutect2
- PPP1R14D | c.256-1020T>G | Intron (SNP) | VAF 12/134 reads (9%) | catalogued as rs1431186300, COSV54542160; called by muse, mutect2
- PREPL | chr2:44318205 T>C | 3'Flank (SNP) | VAF 8/54 reads (15%) | catalogued as rs1325852720; called by muse, mutect2
- SLC7A13 | c.1180-932A>G | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as rs1482617054; called by muse, varscan2
- TCEANC2 | c.*8199A>G | 3'UTR (SNP) | VAF 8/29 reads (28%) | catalogued as rs1356049508; called by muse, varscan2
- TRAPPC9 | c.2811-22223T>C | Intron (SNP) | VAF 16/86 reads (19%) | catalogued as rs769735452; called by muse, varscan2
- TYK2 | c.194-1368T>C | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as rs1386730107; called by muse, mutect2, varscan2
- XIAP | c.*5745G>A | 3'UTR (SNP) | VAF 5/47 reads (11%) | catalogued as rs1387334716, COSV63022957; called by muse, varscan2
- ZNF254 | c.-16G>T | 5'UTR (SNP) | VAF 133/321 reads (41%) | catalogued as COSV100298341; called by muse, mutect2, varscan2
- ZNF99 | c.*3181T>C | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs1193545143; called by muse, varscan2
